MMRF case MMRF_1998 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/fd98803b-0edf-42dc-b3f3-1780111fe48e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Dead; Days to death: 292 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.2 years (23,080 days); ISS stage: II; Days to last known disease status: 292 days; Days to last follow up: 292 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 292 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 162 days; Days to treatment end: 252 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 292.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 1): M Protein 2.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.743 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.464 mg/dL; Immunoglobulin G 28.3 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 3.71 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 320 ×10⁹/L; Creatinine 139 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.5 mmol/L; Albumin 45 g/L; Total Protein 9.1 g/dL; Glucose 4.24 mmol/L; C-Reactive Protein 0.06 mg/dL.
- Day 86 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.061 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.056 mg/dL; Immunoglobulin G 2.9 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3.8 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 14.3 ×10⁹/L; Absolute Neutrophil 13.2 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 15.9 mmol/L.
- Day 164 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.503 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.525 mg/dL; Immunoglobulin G 5.36 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 3.8 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 15.1 ×10⁹/L; Absolute Neutrophil 13.7 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.38 mmol/L; Albumin 49 g/L; Total Protein 7.1 g/dL; Glucose 14.4 mmol/L.

Other clinical attributes
- Day -12: Weight: 105 kg; Height: 183 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1998_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_1998_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
